Somatic mutation profile of tumor specimen ALCH-B1PR-TTP1-A (aliquot ALCH-B1PR-TTP1-A-1-0-D-A76C-36) from ALCHEMIST case ALCH-B1PR, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 83.0 years (30,330 days).
Specimen ALCH-B1PR-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 69a55b07-fbdf-48bf-81b6-273979f87528.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1PR-NB1-A (Blood Derived Normal), aliquot ALCH-B1PR-NB1-A-1-0-D-A76C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/babbc56b-bdc4-45ce-8b2b-0d31301aae58

The open-access MAF lists 26 somatic variants for this specimen: 15 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 9, Nonsense Mutation 1, 5'UTR 1, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2240_2254del p.L747_T751del | In Frame Del (DEL) | VAF 100/810 reads (12%) | hotspot (GDC flag); catalogued as rs121913442, COSV51863059; ClinVar: drug response; called by mutect2, pindel
- APC | c.3890A>T p.D1297V | Missense Mutation (SNP) | VAF 23/525 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV57384421, COSV99965860; called by muse, mutect2
- DCDC1 | c.2957A>G p.K986R (on ENST00000597505 / NM_001367979.1; = p.K93R on NM_020869.3) | Missense Mutation (SNP) | VAF 15/248 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs1179234369; called by muse, mutect2
- PSMD5 | c.413A>C p.N138T | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.109); catalogued as rs747970566; called by muse, mutect2, varscan2
- USP49 | c.1607C>G p.A536G | Missense Mutation (SNP) | VAF 11/251 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1387426245; called by muse, mutect2
- CABP2 | c.397T>C p.F133L | Missense Mutation (SNP) | VAF 9/162 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.43); called by muse, mutect2
- KLHL42 | c.1025G>A p.C342Y | Missense Mutation (SNP) | VAF 24/308 reads (8%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.88); called by muse, mutect2
- OR51E1 | c.932T>A p.V311E | Missense Mutation (SNP) | VAF 6/119 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.046); called by muse, mutect2
- OR51F1 | c.601A>T p.I201F | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.765); called by muse, mutect2
- OTP | c.944C>T p.A315V | Missense Mutation (SNP) | VAF 9/161 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PKP3 | c.1268T>A p.V423D | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- SLC5A11 | c.1202C>A p.T401N | Missense Mutation (SNP) | VAF 10/269 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SPRY1 | c.94G>T p.E32* | Nonsense Mutation (SNP) | VAF 36/443 reads (8%) | called by muse, mutect2
- SPRY1 | c.95A>T p.E32V | Missense Mutation (SNP) | VAF 39/449 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.383); called by muse, mutect2
- ZNF652 | c.554T>G p.V185G | Missense Mutation (SNP) | VAF 20/266 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2
- ABCC8 | c.2634C>T p.D878= | Silent (SNP) | VAF 20/303 reads (7%) | catalogued as rs754554936; called by muse, mutect2
- AQR | c.2937A>G p.Q979= | Silent (SNP) | VAF 14/254 reads (6%) | called by muse, mutect2
- ARHGAP6 | c.1584C>T p.I528= | Silent (SNP) | VAF 44/547 reads (8%) | catalogued as rs150157910; called by muse, mutect2
- BFSP1 | c.582C>T p.I194= | Silent (SNP) | VAF 12/269 reads (4%) | called by muse, mutect2
- ELMOD3 | c.1140G>A p.L380= | Silent (SNP) | VAF 6/118 reads (5%) | called by muse, mutect2
- MED12 | c.2694T>C p.N898= | Silent (SNP) | VAF 24/558 reads (4%) | called by muse, mutect2
- OMP | c.491G>A p.*164= | Silent (SNP) | VAF 3/33 reads (9%) | called by muse, mutect2
- STKLD1 | c.1089G>A p.P363= | Silent (SNP) | VAF 9/98 reads (9%) | catalogued as rs782011615; called by muse, mutect2
- TXNIP | c.232C>T p.L78= | Silent (SNP) | VAF 10/185 reads (5%) | catalogued as rs782697033; called by muse, mutect2
- SLC35B3 | c.-310G>A | 5'UTR (SNP) | VAF 18/420 reads (4%) | called by muse, mutect2
- VAPB | c.*6425C>T | 3'UTR (SNP) | VAF 24/289 reads (8%) | called by muse, mutect2
